Somatic mutation profile of tumor specimen TCGA-EB-A4OY-01A (aliquot TCGA-EB-A4OY-01A-11D-A25O-08) from TCGA case TCGA-EB-A4OY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.1 years (23,771 days).
Specimen TCGA-EB-A4OY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a38373-91be-43c9-9190-389c5229baaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A4OY-10A (Blood Derived Normal), aliquot TCGA-EB-A4OY-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6ba8778-3b89-405f-895f-a74bf054e860

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 41, Silent 13, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD5 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.205); catalogued as COSV50007174; called by muse, mutect2, varscan2
- ARFGEF2 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64211568; called by muse, mutect2, varscan2
- ATP6V1G1 | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65014493; called by muse, mutect2, varscan2
- CXorf58 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV64858963; called by muse, mutect2, varscan2
- DAPK1 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV63792930; called by muse, mutect2
- DDAH2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs761335515, COSV65383591; called by muse, mutect2, varscan2
- DOP1A | c.3721A>T p.I1241F | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52711159; called by muse, mutect2, varscan2
- DUSP4 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53548290; called by muse, varscan2
- EDN1 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65081455; called by muse, mutect2, varscan2
- ESPL1 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 30/143 reads (21%) | catalogued as COSV57764374; called by muse, mutect2, varscan2
- F8 | c.5441A>G p.D1814G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64279883; called by muse, mutect2, varscan2
- FOXP2 | c.1482C>G p.N494K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63495580; called by muse, mutect2, varscan2
- HIP1R | c.851A>C p.E284A | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV53445729; called by muse, mutect2, varscan2
- HIRIP3 | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 8/123 reads (7%) | catalogued as COSV54232068; called by muse, mutect2
- KCNAB3 | c.313A>C p.I105L | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.228); catalogued as COSV58051694; called by muse, mutect2, varscan2
- KDM1B | c.1663T>C p.S555P (on ENST00000449850; = p.S323P on NM_153042.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418268806, COSV52815288; called by muse, mutect2
- KIF18B | c.1502G>A p.G501E (on ENST00000593135 / NM_001265577.2; = p.G513E on NM_001264573.2) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59276983; called by muse, mutect2, varscan2
- KIR2DL1 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.186); catalogued as COSV52416636; called by muse, mutect2, varscan2
- KRT2 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs776227434, COSV100548354, COSV59013195; called by muse, mutect2, varscan2
- KRTAP12-2 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.326); catalogued as COSV59983779; called by muse, mutect2, varscan2
- MAN2A1 | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV54860182; called by muse, mutect2, varscan2
- MAP3K9 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67123228; called by muse, mutect2, varscan2
- MPPED1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs529333273, COSV61986906; called by muse, mutect2
- NLRP8 | c.2769T>A p.N923K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52595471; called by muse, mutect2, varscan2
- NR0B2 | c.321T>A p.F107L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV54260454; called by muse, mutect2, varscan2
- OBSCN | c.9409G>A p.G3137R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV52843333; called by muse, mutect2
- PCLO | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV61676688; called by muse, mutect2, varscan2
- PPP1R3A | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52895169; called by muse, mutect2, varscan2
- RAD54B | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV52596217; called by muse, mutect2
- RBM22 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52273503; called by muse, mutect2, varscan2
- SH3PXD2A | c.546C>G p.N182K | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV60121316; called by muse, mutect2, varscan2
- SI | c.834A>C p.Q278H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52306393; called by muse, mutect2, varscan2
- SLC1A6 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as rs756455637, COSV55673359; called by muse, mutect2, varscan2
- SLC25A3 | c.608C>T p.A203V (on ENST00000228318 / NM_005888.3; = p.A202V on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.517); catalogued as rs1384097884, COSV51848463; called by muse, mutect2, varscan2
- SLC35G3 | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52013139; called by muse, mutect2, varscan2
- SLC9B1 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56476816; called by muse, mutect2, varscan2
- SMC1B | c.3224T>C p.I1075T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62534065; called by muse, mutect2, varscan2
- STK16 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777877967, COSV50284279; called by muse, mutect2
- TARS2 | c.777C>G p.N259K | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV64697209; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1184C>G p.S395* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV64854542; called by muse, mutect2, varscan2
- TRIM37 | c.1074T>A p.N358K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV51889810; called by muse, mutect2, varscan2
- TUBA3C | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV101262746, COSV67140213; called by muse, mutect2, varscan2
- VPS13B | c.4361C>A p.T1454K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1232811849, COSV62161155; called by muse, mutect2, varscan2
- ZNF10 | c.937A>C p.K313Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50216141; called by muse, mutect2, varscan2
- ZZEF1 | c.751A>C p.K251Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.289); catalogued as COSV67560815; called by muse, mutect2, varscan2
- ADNP | c.213A>G p.T71= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV62427155; called by muse, mutect2, varscan2
- ALDH16A1 | c.2007G>A p.P669= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs1159407147, COSV53197562; called by muse, mutect2
- ARHGEF15 | c.1449G>A p.V483= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1426358670, COSV62726888; called by muse, mutect2
- C2CD2 | c.1791C>T p.V597= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV61600843; called by muse, mutect2
- FNDC7 | c.1761T>G p.T587= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV54758842; called by muse, mutect2, varscan2
- N4BP1 | c.1791A>G p.R597= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs766793385, COSV52214091; called by muse, mutect2, varscan2
- NCOA3 | c.1005C>T p.F335= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV100508198, COSV59074533; called by muse, mutect2, varscan2
- NDUFS8 | c.417G>T p.R139= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55837881; called by muse, mutect2, varscan2
- OR4E2 | c.195T>C p.N65= | Silent (SNP) | VAF 51/268 reads (19%) | catalogued as rs1428679017, COSV57732454; called by muse, mutect2, varscan2
- PSMD3 | c.1368C>G p.G456= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as COSV52860188; called by muse, mutect2, varscan2
- RPGRIP1L | c.435C>T p.Y145= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as COSV50921171; called by muse, mutect2, varscan2
- SEC31A | c.1854C>T p.F618= (on ENST00000355196 / NM_001318120.1; = p.F579= on NM_016211.4) | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs149546168; called by muse, mutect2, varscan2
- SLC24A1 | c.1815T>C p.H605= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV56054733; called by muse, mutect2
